Gene-level copy-number profile of specimen HCM-BROD-0869-C43-85A from HCMI case HCM-BROD-0869-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 45.7 years (16,703 days).
Specimen HCM-BROD-0869-C43-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b5b8c2c2-44b3-440a-bae3-9ed786033780.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0869-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/dbf9422c-991b-4fe3-89f2-b56d54d7fed5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 313; copy number 2: 15,255; copy number 3: 17,406; copy number 4: 14,198; copy number 5: 5,354; copy number 6: 4,792; copy number 7: 1,510; copy number 8: 47; copy number 9: 4.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr6:170,615,515–170,738,536, 5 genes: AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr11:65,423,960–65,506,516, 10 genes: AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–3): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–3): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–3): IGHV3-43.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,561 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–120,467,739, 47 genes, copy number 8 (within-gene range 6–8): PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8.
- chr1:120,849,674–121,009,291, 8 genes, copy number 7–9: AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, U1.
- chr9:67,832,765–70,414,624, 45 genes, copy number 7: ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2, APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P, MAMDC2-AS1, MAMDC2, RNU2-5P, SMC5-AS1, RPL24P8, SMC5, AL162390.1, Y_RNA, KLF9.
- chr9:71,589,601–75,198,177, 48 genes, copy number 7: RPL35AP21, CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.1, AL512594.1, RNA5SP286, AL513124.1, AL355674.1, RORB-AS1, RORB, AL137018.1, TRPM6, RN7SKP47, RPSAP75, RNU6-445P, AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3, NMRK1, OSTF1, Y_RNA, RNU6-1228P.
- chr9:75,579,669–76,993,108, 16 genes, copy number 7: AL353780.1, OTX2P1, PCSK5, RBM22P5, RFK, RPSAP9, GCNT1, H3P32, PPIAP87, PRUNE2, PCA3, AL359314.1, AL390239.1, DNAJB5P1, LYPLA2P3, AL353637.1.
- chr16:35,134,514–35,912,516, 70 genes, copy number 7 (broad region; genes not listed).
- chr17:44,924,709–45,109,016, 8 genes, copy number 7 (within-gene range 5–7): KIF18B, MIR6783, AC015936.1, NMT1, C1QL1, AC015936.2, DCAKD, Y_RNA.
- chr17:52,390,515–80,035,872, 734 genes, copy number 7 (broad region; genes not listed).
- chr20:30,214,765–52,670,578, 585 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 313. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
